Gene-level copy-number profile of tumor specimen HTMCP-03-06-02125-01A from CGCI case HTMCP-03-06-02125, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 26.9 years (9,843 days).
Specimen HTMCP-03-06-02125-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e40a1f67-015a-4ec1-b338-3004ce238d91.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02125-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/ed116334-c466-4340-bf5b-c0f3c7a539c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 5,228; copy number 2: 40,840; copy number 3: 11,789; copy number 4: 321; copy number 5: 22; copy number 6: 97; copy number 7: 14; copy number 8: 17; copy number 11: 28.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr8:12,362,019–12,388,296, 3 genes: FAM66A, AC087203.1, AC087203.2.
- chr8:12,628,476–12,638,602, 2 genes: RPS3AP35, AC068587.3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:9,799,423–9,803,784, 1 gene (within-gene range 0–2): AL513422.1.
- chr22:18,178,038–18,653,617, 20 genes: FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 178 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,051,944–88,168,729, 5 genes, copy number 5: CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38.
- chr3:90,202,316–90,261,708, 2 genes, copy number 5: PROS2P, HSPE1P19.
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,256,337–38,330,935, 13 genes, copy number 7 (within-gene range 4–7): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr14:21,924,063–22,503,814, 76 genes, copy number 5–11 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.
- chr22:16,690,103–16,821,699, 4 genes, copy number 6 (within-gene range 4–6): VWFP1, AC005301.2, LINC01665, XKR3.
- chr22:20,198,729–21,396,590, 76 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,751. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
